Surgical pathology report (de-identified scan), TCGA case TCGA-MQ-A4LM, project TCGA-MESO (Mesothelioma), tissue source site Washington University - NYU, specimen TCGA-MQ-A4LM-01A (Primary Tumor).

[page 1 of 5]
Result type: Report
Result date:
Result status:
Result title:
Performed by:

*** Final Report ***

SPECIMEN DESCRIPTION

ANTERIOR THORACOSCOPY SITE
PERICARDIUM
RIB RIGHT
LEVEL 4
LEVEL 10
LEVEL 7
LEVEL 9
PHRENIC NERVE
VICERA PLEURA
PLEURA
POSTERIOR THORACOSCOPY SITE
DIAPHRAGM

ICD-0-3
Mesothelioma, biphasic, NOS 9053/3
Site: pleura, NOS C38.4
hw
10/4/12

SURGICAL PATHOLOGY REPORT

LOCATION: [REDACTED]

PATHOLOGY NO.: [REDACTED]
HOSPITAL ID: [REDACTED]
PATIENT ID:

HOSPITAL NO.: [REDACTED]
ACCOUNT NO.: [REDACTED]
DATE RECEIVED:
DATE OF PROCEDURE:
ACCN REQ. NO.: NOT GIVEN
ATTENDING PHYS:

PATIENT'S NAME: [REDACTED]
AGE/SEX/DOB:
PHYSICIAN(S):
COPY TO:
REFERRING PHYS:

DIAGNOSIS:

A. LABELED ANTERIOR THORACOSCOPY SITE, EXCISION:
SKIN AND SUBCUTANEOUS TISSUE WITH SUTURE GRANULOMAS AND FOREIGN BODY GIANT CELL
REACTION. NO EVIDENCE OF MALIGNANCY.

B. LABELED PERICARDIUM, EXCISION:
MALIGNANT MESOTHELIOMA, MIXED TYPE, SEE COMMENT

Printed by:
Printed on:

Page 1 of 5
(Continued)

[page 2 of 5]
[REDACTED]

C. LABELED RIGHT RIB, EXCISION:
PORTION OF BONE AND BONE MARROW WITH NO EVIDENCE OF TUMOR

D. LABELED LEVEL 4 LYMPH NODE, EXCISION:
NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

E. LABELED LEVEL 10 LYMPH NODE, EXCISION:
NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

F. LABELED LEVEL 7 LYMPH NODE, EXCISION:
NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

G. LABELED LEVEL 9 LYMPH NODE, EXCISION:
NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

H. LABELED PHRENIC NERVE, EXCISION:
NO EVIDENCE OF MALIGNANCY.

I. LABELED VISCERAL PLEURA, EXCISION:
FIBROCONNECTIVE TISSUE WITH FIBRINOUS EXUDATE AND CHRONIC INFLAMMATION. NO
EVIDENCE OF MALIGNANCY.

J. LABELED PLEURA, EXCISION:
MALIGNANT MESOTHELIOMA, MIXED TYPE
TWO LYMPH NODES WITH MILD FOLLICULAR HYPERPLASIA AND NO EVIDENCE OF MALIGNANCY
(0/2).

K. LABELED POSTERIOR THORACOSCOPY SITE, EXCISION:
SKIN AND SUBCUTANEOUS TISSUE WITH SUTURE GRANULOMAS AND FOREIGN BODY GIANT CELL
REACTION. NO EVIDENCE OF MALIGNANCY.

L. LABELED DIAPHRAGM, EXCISION:
MALIGNANT MESOTHELIOMA, MIXED TYPE

NOTE: Histologic examination of the submitted pericardium, pleura, and
diaphragm show the mixed phase malignant mesothelioma of epithelioid and
spindle cells components interspersed by collagenous and fibrous stroma. There
is moderate nuclear atypia and scattered mitotic figures along with a few
atypical mitoses. The tumor infiltrates into the adjacent adipose tissue and
focal lymphoid infiltration. In the specimen labeled (diaphragm) the tumor is
adherent to skeletal muscle fibers.

SPECIMEN: A ANTERIOR THORACOSCOPY SITE
B PERICARDIUM
C RIB RIGHT
D LEVEL 4
E LEVEL 10
F LEVEL 7

Printed by:
Printed on:

Page 2 of 5
(Continued)

[page 3 of 5]
[REDACTED]

G LEVEL 9
H PHRENIC NERVE
I VICERA PLEURA
J PLEURA
K POSTERIOR THORACOSCOPY SITE
L DIAPHRAGM
OPERATION: RIGHT EXTRAPLEURAL PNEUMONECTOMY
PRE-OP DIAGNOSIS: MESOTHELIOMA
POST-OP DIAGNOSIS: SAME
CLINICAL DATA: NOT GIVEN

GROSS DESCRIPTION:

A. Received fresh labeled anterior thoracoscopy site. The specimen consists of a piece of adipose tissue measuring 4.4 x 2.2 x 0.8 cm, partially covered by an ellipse of white-tan skin measuring 3.6 x 1.4 cm. A longitudinal scar is noted in the middle of the skin measuring 2 cm in length. The cut surfaces show the specimen to be composed of 95% of adipose tissue and 5% fibrous tissue. The representative sections are submitted in two cassettes.

B. Received fresh labeled pericardium. The specimen consists of a piece of pericardium and attached adipose tissue. The pericardium measures 7.5 x 5 cm and is pink-tan, and the adipose tissue measures 5.5 x 5 x 1.5 cm. Numerous tan, rubbery nodules are attached both to the surface of the pericardium and the attached adipose tissue, the largest, which is attached to the pericardium measures 1.1 cm in maximal dimension. The representative sections are submitted in four cassettes.

C.

D. Received fresh labeled level 4. The specimen consists of multiple pieces of tan to red soft tissue ranging in size from 0.7 x 0.6 x 0.4 cm to 2.5 x 1 x 0.5 cm. The specimen is submitted in toto in two cassettes.

E. Received fresh labeled level 10. The specimen consists of a dark red to dark gray lymph node measuring 2 x 1.3 x 0.9 cm. The lymph node is multisectioned. The cut surfaces showed dark gray, anthracotic surfaces. The specimen is submitted in toto in three cassettes.

F. Received fresh labeled level 7. The specimen consists of multiple pieces of dark red anthracotic tissue compatible with lymphoid tissue and ranging in size from 1.7 x 1 x 0.5 cm to 3 x 1.1 x 0.5 cm. The specimen is submitted in toto in five cassettes.

G. Received fresh labeled level 9. The specimen consists of a piece of tan to dark red soft tissue measuring 1.5 x 1 x 0.4 cm. The specimen is submitted in toto in one cassette.

H. Received fresh labeled phrenic nerve. The specimen consists of an elongated piece of tan to yellow soft tissue measuring 5.1 cm in length and ranging from 0.2 to 0.5 cm in thickness. The specimen is serially sectioned and the

[page 4 of 5]
[REDACTED]

representative sections are submitted in two cassettes.

I. Received fresh labeled visceral pleura. The specimen consists of multiple pieces of pink-tan serosal tissue compatible with pleura which are smooth and shiny on one surface and roughened on the other surface. They range in size from 1.8 x 0.9 cm through 11 x 5.7 cm and measure less than 0.2 cm in thickness.

J. Received fresh labeled pleura. The specimen consists of a flat, pink-tan fibromembranous tissue compatible with pleura which measures 33 x 24 cm on its surface and ranges from 0.1 to 1 cm in thickness. Multiple nodularities are noted in different areas of the specimen and range in size from 0.3 cm to 3.5 x 2.3 cm. A large plaque like, appearance of tan to yellow thickening is also noted in one area and measures 6.5 x 5.5 cm. Areas of attached adipose tissue are also noted and measures 9 x 5 x 2.3 cm. The cut surfaces of the plaque in the nodular areas show rubbery, homogenous tan tissue. The representative sections are submitted in eight cassettes. The specimen also includes another piece of adipose tissue which is partly covered by serosal tissue. Representative sections including sections of a nodular area and a lymph node are submitted in cassettes #9 and #10.

K. Received fresh labeled posterior thoracoscopy site. The specimen consists of an ellipse of skin with underlying subcutaneous and adipose tissue. The skin ellipse is white-tan and measures 4.7 x 3 cm and the underlying tissue has a depth of 4 cm. The specimen is serially sectioned. The cut surfaces show 75% adipose tissue and 25% fibrous tissue, the fibrous tissue is mainly localized to the central area of the specimen and ellipse stellate shaped fashion. The representative sections are submitted in two cassettes.

L. Received fresh labeled diaphragm. The specimen consists of a portion of diaphragm measuring 25 x 13 cm on its surface and ranging in thickness from 0.5 to 0.8 cm. The thicker areas are located in the middle of the specimen and comprise a firm, tan plaque in this area. This plaque is noted especially on the pleural surface and measures 10.5 x 6.5 cm. The peritoneal surface is partly covered by serosa in an area measuring 15 x 10 cm and no significant abnormality is noted on this surface. Other nodular areas are noted in the periphery of the pleural surface and range from 0.5 to 1.7 cm in their maximum dimensions. The cut surfaces show part of the plaque-like area to be composed of dense fibrous tissue compatible with the membranous portion of the diaphragm, however, in some areas, there is tan rubbery thickening overlying the fibrous tissue. These thickenings are similar to the nodularities in the previous portions. The representative sections are submitted in six cassettes.

CPT CODE: [REDACTED]

ELECTRONIC SIGNATURE:

Printed by:
Printed on:

Page 4 of 5
(Continued)

[page 5 of 5]
Completed Action List
* Perform by

Printed by:
Printed on:

Page 5 of 5
(End of Report)

9/23/12

Source: NCI Genomic Data Commons file bf3cdea8-a3ed-4002-9bf2-d656be44f918 (TCGA-MQ-A4LM.01985FC2-F0A2-4B31-B7D2-37C86717AC8F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).